CCDI case PBCFWI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/e9c899aa-81fe-4cfe-adb0-7ab9ff1241c1

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,119 days).

Biospecimens (3 samples)
- Samples 0DTFRE, 0DTFRO (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTFRU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
